Somatic mutation profile of tumor specimen TCGA-22-5480-01A (aliquot TCGA-22-5480-01A-01D-1632-08) from TCGA case TCGA-22-5480, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.4 years (24,245 days).
Specimen TCGA-22-5480-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fffcd34-89c7-4b9d-a9ca-15d76f8bcc9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-5480-11A (Solid Tissue Normal), aliquot TCGA-22-5480-11A-01D-1632-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9013eb02-8887-4c9a-a4a5-106fdaba5c7d

The open-access MAF lists 166 somatic variants for this specimen: 124 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 36, Nonsense Mutation 6, Frame Shift Del 4, RNA 2, Intron 2, Splice Region 2, Nonstop Mutation 1, 5'UTR 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.343); catalogued as rs11540654, CM115383, CM134053, CM984590, COSV52662399, COSV52668419, COSV52680444, COSV53132492; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCF3 | c.1719T>A p.S573R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV53053173; called by muse, mutect2, varscan2
- ABHD6 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV55909034; called by muse, mutect2, varscan2
- ADGRG7 | c.1690C>T p.R564W | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as rs373804273, COSV56297862; called by muse, mutect2, varscan2
- ADGRV1 | c.7210G>A p.G2404S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV67987730; called by muse, mutect2
- AFF1 | c.528A>T p.K176N | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV57120905; called by muse, mutect2, varscan2
- AHNAK | c.15376T>G p.L5126V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV57217145; called by muse, mutect2, varscan2
- AK9 | c.43A>G p.I15V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.769); catalogued as COSV53421761; called by muse, mutect2, varscan2
- ANKRD50 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72385750; called by muse, mutect2, varscan2
- ARID4B | c.2944G>T p.V982L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV51605256; called by muse, mutect2, varscan2
- B4GALNT3 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs768914293, COSV56753890; called by muse, mutect2, varscan2
- BANK1 | c.119G>T p.W40L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59844662; called by muse, mutect2, varscan2
- BPGM | c.509A>G p.N170S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV61324965; called by muse, mutect2, varscan2
- BPTF | c.6239T>G p.I2080R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV58839468; called by muse, mutect2
- C3orf70 | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58588496; called by muse, mutect2, varscan2
- CALCOCO1 | c.612G>C p.G204= | Splice Region (SNP) | VAF 96/294 reads (33%) | catalogued as COSV50415338; called by muse, mutect2, varscan2
- CCDC141 | c.3126C>A p.C1042* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV55375738, COSV99836288; called by muse, mutect2, varscan2
- CCDC80 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 28/88 reads (32%) | catalogued as COSV52817616; called by muse, mutect2, varscan2
- CD93 | c.1752C>A p.F584L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV55664220, COSV55666055; called by muse, mutect2, varscan2
- CDH19 | c.2114A>G p.E705G | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50962214; called by muse, mutect2, varscan2
- CFAP251 | c.1625G>C p.G542A | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV56611559, COSV56616682; called by muse, mutect2, varscan2
- CHEK1 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54023894; called by muse, mutect2, varscan2
- CLCA1 | c.2096C>A p.P699H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV52328564; called by muse, mutect2, varscan2
- CLCN3 | c.1102C>G p.P368A | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61627566, COSV61628552; called by muse, mutect2, varscan2
- CRB1 | c.3916T>C p.C1306R | Missense Mutation (SNP) | VAF 106/211 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV66331115; called by muse, mutect2, varscan2
- DACH1 | c.1953G>C p.K651N (on ENST00000619232 / NM_001366712.1; = p.K397N on NM_004392.6) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as COSV57505136; called by muse, mutect2, varscan2
- DIP2C | c.4670A>T p.*1557Lext*21 | Nonstop Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV55162755; called by muse, mutect2, varscan2
- DNER | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV59161849, COSV59168801; called by muse, mutect2, varscan2
- DPH6 | c.567G>C p.E189D | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV56615454; called by muse, mutect2, varscan2
- EBF2 | c.1385C>G p.S462C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as COSV68778587; called by muse, mutect2
- EIF2B1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV71194288; called by muse, mutect2, varscan2
- EPHA6 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.602); catalogued as COSV67576800; called by muse, mutect2
- FAM3C | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV63435797; called by muse, mutect2, varscan2
- FCER1A | c.542G>T p.W181L | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.078); catalogued as COSV63667532; called by muse, mutect2, varscan2
- FCER1A | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.625); catalogued as rs537550419, COSV63667536; called by muse, mutect2, varscan2
- FEM1A | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1023632762, COSV54163449; called by muse, mutect2
- FRAS1 | c.7151G>T p.R2384L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV53619321; called by muse, mutect2, varscan2
- FRY | c.6553C>G p.L2185V | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66567942, COSV66572172; called by muse, mutect2, varscan2
- GOLGA2 | c.2917A>G p.I973V | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as rs754164457, COSV57852703; called by muse, mutect2, varscan2
- GRIN3A | c.2220G>T p.W740C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.462); catalogued as COSV62455044; called by muse, mutect2, varscan2
- GTPBP4 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs369802399; called by muse, mutect2, varscan2
- HAPLN1 | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV57148953; called by muse, mutect2, varscan2
- HCFC2 | c.2171A>T p.N724I | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.185); catalogued as COSV57558934; called by muse, mutect2, varscan2
- HSPD1 | c.370G>C p.A124P | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as COSV52099033; called by muse, mutect2, varscan2
- IGSF8 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV58758383; called by muse, mutect2, varscan2
- INTS6 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV60878789; called by muse, mutect2, varscan2
- ISOC1 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as rs755047077, COSV51492050; called by muse, mutect2, varscan2
- ITGB4 | c.1127A>G p.D376G | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.345); catalogued as COSV52327719; called by muse, mutect2, varscan2
- KCNQ5 | c.1989C>A p.S663R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1322487368, COSV59665099; called by muse, mutect2, varscan2
- KIAA1109 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV52678005; called by muse, mutect2, varscan2
- KIAA1549 | c.319C>T p.L107F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as COSV54317357; called by muse, mutect2, varscan2
- KRT72 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV53374788; called by muse, mutect2, varscan2
- LAMA1 | c.6781C>G p.P2261A | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as COSV67536934, COSV67544239; called by muse, varscan2
- LAMA1 | c.4665C>A p.S1555= | Splice Region (SNP) | VAF 23/74 reads (31%) | catalogued as COSV67538973; called by muse, mutect2, varscan2
- LAMA3 | c.2284G>A p.A762T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1568218642, COSV58071136; called by muse, mutect2, varscan2
- LSM8 | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.052); catalogued as COSV50800516; called by muse, mutect2, varscan2
- MASP1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51460691; called by muse, mutect2, varscan2
- MIA2 | c.1699G>A p.D567N | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.492); catalogued as COSV54484114; called by muse, mutect2, varscan2
- MMP16 | c.988A>G p.T330A | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV54170707; called by muse, mutect2, varscan2
- MPO | c.2013G>T p.K671N | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.051); catalogued as COSV51859850; called by muse, mutect2, varscan2
- MPP7 | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV61733884; called by muse, varscan2
- MRGPRX1 | c.818T>C p.F273S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57107795; called by muse, mutect2, varscan2
- MUC16 | c.12875G>A p.G4292D | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.023); catalogued as COSV67473702; called by muse, mutect2, varscan2
- MUC5AC | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); catalogued as COSV62254293; called by muse, mutect2, varscan2
- N4BP2L2 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 26/95 reads (27%) | catalogued as COSV57228778; called by muse, mutect2, varscan2
- NIPA2 | c.682T>C p.C228R | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57410948; called by muse, mutect2, varscan2
- NSD3 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57670894; called by muse, mutect2
- OR4C16 | c.335T>A p.I112N | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as rs143747626; called by muse, mutect2, varscan2
- OR4D10 | c.927T>G p.D309E | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101597001, COSV73260075; called by mutect2, varscan2
- OR5D18 | c.313T>A p.F105I | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV61737542; called by muse, mutect2, varscan2
- PAPOLB | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.661); catalogued as COSV68201666; called by muse, mutect2, varscan2
- PARD3B | c.1520C>T p.A507V | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs149158367, COSV62515401; called by muse, mutect2, varscan2
- PCDHA2 | c.826G>T p.E276* | Nonsense Mutation (SNP) | VAF 56/77 reads (73%) | catalogued as COSV65367939, COSV65368049; called by muse, mutect2, varscan2
- PCDHGB2 | c.1088G>A p.G363E | Missense Mutation (SNP) | VAF 39/57 reads (68%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53967568; called by muse, mutect2, varscan2
- PGBD4 | c.1447A>G p.I483V | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV56628155; called by muse, mutect2, varscan2
- PODXL2 | c.526G>C p.E176Q | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.378); catalogued as COSV61065649; called by muse, mutect2, varscan2
- POPDC3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV54644584; called by muse, mutect2, varscan2
- PSG1 | c.383A>T p.D128V | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs1058668, COSV54951605; called by muse, mutect2, varscan2
- PTPN7 | c.109C>T p.R37* (on ENST00000495688; = p.R76* on NM_002832.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as rs149516769, COSV58313272; called by muse, mutect2, varscan2
- RIT2 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58668027; called by muse, mutect2, varscan2
- RNASE10 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); catalogued as COSV60517876; called by muse, mutect2, varscan2
- RNF26 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60990765; called by muse, mutect2, varscan2
- ROBO3 | c.878A>T p.K293M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67301022; called by muse, mutect2, varscan2
- RPTN | c.1672C>G p.H558D | Missense Mutation (SNP) | VAF 173/936 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); catalogued as COSV60167602; called by muse, mutect2, varscan2
- RSAD2 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV65908449; called by muse, mutect2, varscan2
- RYR3 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV66794932; called by muse, mutect2, varscan2
- S1PR1 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV59513501, COSV59513537; called by muse, mutect2, varscan2
- SF3B1 | c.3139G>T p.A1047S | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV59217287; called by muse, mutect2, varscan2
- SLC12A8 | c.1955T>A p.M652K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV58867083; called by muse, mutect2, varscan2
- SLC8A1 | c.1094G>T p.R365L | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777983552, COSV60473916, COSV60484670; called by muse, mutect2, varscan2
- SOCS6 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV67546595; called by muse, mutect2, varscan2
- SPRED2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); catalogued as COSV100710312, COSV62693495; called by muse, mutect2, varscan2
- SPTA1 | c.2321G>T p.R774L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs765951388, COSV63750480, COSV63754978; called by muse, mutect2, varscan2
- SRSF11 | c.680G>C p.R227P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63937190; called by muse, mutect2, varscan2
- ST8SIA4 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 37/63 reads (59%) | PolyPhen possibly damaging (0.602); catalogued as rs150785295; called by muse, mutect2, varscan2
- ST8SIA6 | c.650del p.P217Qfs*17 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | catalogued as COSV104427254; called by mutect2, pindel, varscan2
- SVIL | c.5678A>G p.E1893G (on ENST00000355867 / NM_021738.3; = p.E1467G on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs1057485278, COSV63444401; called by muse, mutect2, varscan2
- TAB3 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.813); catalogued as COSV55838007; called by muse, mutect2, varscan2
- TGFBI | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1215819431, COSV59351988; called by muse, mutect2, varscan2
- TGIF2LX | c.199del p.D67Tfs*120 | Frame Shift Del (DEL) | VAF 33/79 reads (42%) | catalogued as COSV52215049; called by mutect2, pindel, varscan2
- TGOLN2 | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 65/121 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56406458; called by muse, mutect2, varscan2
- TMEM132D | c.2421T>G p.S807R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.101); catalogued as rs773066809, COSV67160753; called by muse, mutect2, varscan2
- TMEM178A | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 67/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56142281; called by muse, mutect2, varscan2
- TMEM38B | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.09); PolyPhen benign (0.377); catalogued as COSV65950259; called by muse, mutect2, varscan2
- TMTC2 | c.2350A>T p.N784Y | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58272374; called by muse, mutect2, varscan2
- TNFSF14 | c.546C>A p.S182R | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.897); catalogued as COSV55590983; called by muse, mutect2, varscan2
- TNIK | c.3377A>C p.D1126A | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52685315; called by muse, mutect2, varscan2
- TNXB | c.6193C>A p.Q2065K (on ENST00000647633; = p.Q1818K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.939); catalogued as COSV64480891; called by muse, mutect2, varscan2
- TOX2 | c.1172C>A p.P391H (on ENST00000358131 / NM_001098798.2; = p.P367H on NM_032883.3) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.867); catalogued as COSV57888219; called by muse, mutect2, varscan2
- TRPC4AP | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0.007); catalogued as COSV52681000; called by muse, mutect2, varscan2
- TTN | c.61415G>C p.R20472T (on ENST00000591111; = p.R13048T on NM_003319.4) | Missense Mutation (SNP) | VAF 50/167 reads (30%) | PolyPhen probably damaging (0.996); catalogued as COSV60132529; called by muse, mutect2, varscan2
- WDR45B | c.239A>T p.N80I | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV66408503; called by muse, mutect2, varscan2
- ZCCHC8 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60318685; called by muse, mutect2, varscan2
- ZKSCAN3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.207); catalogued as rs199522744; called by muse, mutect2, varscan2
- ZMYM3 | c.2384C>G p.T795S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV58738650; called by muse, mutect2, varscan2
- ZNF10 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV50212836, COSV50213880; called by muse, mutect2, varscan2
- ZNF146 | c.116C>G p.T39R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs753111926, COSV61932007; called by muse, mutect2, varscan2
- ZNF221 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52109916; called by muse, mutect2, varscan2
- ZNF804B | c.883A>G p.T295A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV60832718; called by muse, mutect2, varscan2
- ZNF91 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.201); catalogued as rs1254552468, COSV56086045; called by muse, mutect2, varscan2
- ZSWIM2 | c.1267G>T p.D423Y | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as rs774611083, COSV54576359; called by muse, mutect2, varscan2
- B2M | c.100_122del p.P34Ffs*15 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.2829dup p.P944Tfs*4 | Frame Shift Ins (INS) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- SLC6A4 | c.346del p.A116Hfs*146 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- ACSS2 | c.1164T>C p.Y388= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as rs201529980, COSV53625503; called by muse, mutect2, varscan2
- ADAMTS20 | c.3522C>A p.A1174= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV67133358; called by muse, mutect2, varscan2
- CCDC42 | c.759C>A p.T253= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as COSV53449049; called by muse, mutect2, varscan2
- CRACR2A | c.405C>G p.R135= | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV52914202; called by muse, mutect2, varscan2
- DAPK1 | c.3454C>T p.L1152= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as rs756576358, COSV100800676, COSV63788406; called by muse, mutect2, varscan2
- DBF4B | c.534A>G p.G178= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV59261277; called by muse, mutect2, varscan2
- FCER1A | c.660A>G p.T220= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as COSV63667541; called by muse, mutect2, varscan2
- FSTL5 | c.2385G>C p.R795= | Silent (SNP) | VAF 31/133 reads (23%) | catalogued as COSV60201406; called by muse, mutect2
- FZD2 | c.303C>A p.T101= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs781591909, COSV59529323; called by muse, mutect2, varscan2
- GABRB1 | c.1413C>T p.Y471= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as COSV54986207; called by muse, mutect2, varscan2
- GPR63 | c.27G>T p.A9= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs756539591, COSV57739572, COSV57741684; called by muse, mutect2, varscan2
- HACE1 | c.1128A>T p.T376= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV53503557; called by muse, mutect2, varscan2
- KCTD8 | c.1209A>C p.P403= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV63590600; called by muse, mutect2, varscan2
- LAMA1 | c.6861T>C p.Y2287= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV67538969; called by muse, varscan2
- LPA | c.3579C>G p.S1193= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV60303814; called by muse, mutect2, varscan2
- MTG1 | c.903A>T p.A301= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV58154163; called by muse, mutect2, varscan2
- NLRP4 | c.294C>A p.T98= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs149802462; called by muse, mutect2, varscan2
- NMD3 | c.441A>G p.V147= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as COSV63618758; called by muse, mutect2, varscan2
- NME9 | c.513C>A p.A171= (on ENST00000333911 / NM_001349024.2; = p.A110= on NM_178130.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV58619515; called by muse, mutect2, varscan2
- OR12D2 | c.366G>T p.V122= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV65828462; called by muse, mutect2
- OR4C16 | c.336C>A p.I112= | Silent (SNP) | VAF 38/144 reads (26%) | catalogued as COSV58942537; called by muse, mutect2, varscan2
- OR51T1 | c.378G>A p.V126= | Silent (SNP) | VAF 42/122 reads (34%) | catalogued as COSV100434485, COSV59026094; called by muse, mutect2, varscan2
- OR6B1 | c.474G>A p.A158= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs562215999, COSV68770285; called by muse, mutect2
- OR9G4 | c.48T>A p.G16= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57248892; called by muse, mutect2, varscan2
- PCDHB8 | c.1617C>G p.S539= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as COSV50778233; called by muse, mutect2, varscan2
- PCDHGA10 | c.603G>A p.E201= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as COSV53967578; called by muse, mutect2, varscan2
- PIGZ | c.825G>A p.T275= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1261349332, COSV53013908; called by muse, mutect2
- PKP4 | c.957G>C p.T319= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV67677721; called by muse, mutect2, varscan2
- PNLIPRP2 | c.264G>A p.K88= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100077785, COSV53944451; called by mutect2, varscan2
- PRAMEF2 | c.1200C>T p.H400= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as rs747037586, COSV53576372; called by muse, mutect2, varscan2
- PRKCSH | c.1251G>A p.E417= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as COSV52952085; called by muse, mutect2, varscan2
- RUBCNL | c.87G>T p.S29= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV59785622, COSV59789705; called by muse, mutect2
- TEX13A | c.382C>A p.R128= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV61162800; called by muse, mutect2, varscan2
- TFAP2D | c.261C>G p.P87= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV50410911, COSV50417767, COSV50426329; called by muse, mutect2, varscan2
- TTN | c.28791T>C p.D9597= (on ENST00000591111; = p.D8670= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV60132566; called by muse, mutect2, varscan2
- ZBTB24 | c.366A>T p.V122= | Silent (SNP) | VAF 27/136 reads (20%) | catalogued as COSV57782421; called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3604G>A | Intron (SNP) | VAF 16/75 reads (21%) | catalogued as rs759262457, COSV99431230; called by muse, mutect2, varscan2
- KIR3DX1 | n.381C>A | RNA (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99683299; called by muse, mutect2, varscan2
- MIR1269A | n.96G>C | RNA (SNP) | VAF 15/43 reads (35%) | called by muse, varscan2
- NIN | chr14:50723618 C>T | 3'Flank (SNP) | VAF 23/41 reads (56%) | catalogued as COSV55394820; called by muse, mutect2, varscan2
- NXPE4 | c.-1C>T | 5'UTR (SNP) | VAF 29/71 reads (41%) | catalogued as COSV100970431; called by muse, mutect2
- PDE4D | c.456-59403C>A | Intron (SNP) | VAF 23/37 reads (62%) | catalogued as COSV100506501; called by muse, mutect2, varscan2
